Somatic mutation profile of tumor specimen TCGA-E7-A678-01A (aliquot TCGA-E7-A678-01A-11D-A30E-08) from TCGA case TCGA-E7-A678, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: Low Grade; Age at diagnosis: 55.2 years (20,169 days).
Specimen TCGA-E7-A678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c8adba2-7fd4-49a1-ae2a-035565928f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A678-10A (Blood Derived Normal), aliquot TCGA-E7-A678-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bf92209-1c54-482f-b3bc-89c97dbcac29

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 34, Silent 14, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.385-2A>T p.X129_splice | Splice Site (SNP) | VAF 13/14 reads (93%) | hotspot (GDC flag); catalogued as COSV65037583, COSV65048184; called by muse, mutect2, varscan2
- ABCC4 | c.3591A>G p.I1197M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65318300; called by muse, mutect2, varscan2
- ABCC5 | c.1728G>T p.R576S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55596390; called by muse, mutect2, varscan2
- AKAP13 | c.5584A>T p.I1862F (on ENST00000394518 / NM_007200.5; = p.I1866F on NM_006738.6) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63469840; called by muse, mutect2, varscan2
- CCDC141 | c.2211G>C p.L737F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs753778696, COSV55382412; called by muse, mutect2, varscan2
- DAAM1 | c.1922A>G p.D641G | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62839800; called by muse, mutect2, varscan2
- DNMT3B | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1369174968, COSV52423393; called by muse, mutect2, varscan2
- DSPP | c.195T>A p.D65E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV56816332; called by muse, mutect2, varscan2
- EP300 | c.3764A>G p.H1255R | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54345540, COSV54345562; called by muse, mutect2, varscan2
- FCAR | c.35-1G>C p.X12_splice | Splice Site (SNP) | VAF 60/124 reads (48%) | catalogued as COSV62031889; called by muse, mutect2, varscan2
- FOXA1 | c.672C>A p.F224L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51645367; called by muse, mutect2, varscan2
- GLUL | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs144782603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIVEP3 | c.3475T>C p.S1159P | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1247115338, COSV56023559; called by muse, mutect2, varscan2
- HMGCR | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 63/135 reads (47%) | catalogued as COSV99843492; called by muse, mutect2, varscan2
- HRG | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1455246341, COSV51648272; called by muse, mutect2, varscan2
- JAKMIP3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs199726287, COSV53829249; called by muse, mutect2, varscan2
- KLRG1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs766573926, COSV56944270, COSV56945047; called by muse, mutect2, varscan2
- LRRK2 | c.7337G>A p.R2446H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs200795955, COSV54151918; called by muse, mutect2, varscan2
- MCTP1 | c.911A>T p.N304I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56533217; called by muse, mutect2, varscan2
- MKI67 | c.3640C>A p.P1214T | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV64076946; called by muse, mutect2, varscan2
- MUC16 | c.42892C>T p.Q14298* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101110098; called by muse, mutect2, varscan2
- MYH2 | c.5086G>T p.A1696S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV55448319, COSV99819808; called by muse, mutect2, varscan2
- NFATC3 | c.586T>A p.L196M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773998520, COSV60479736; called by muse, mutect2, varscan2
- NRP2 | c.1511A>T p.Q504L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55935383; called by muse, mutect2, varscan2
- PDZRN3 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55215338; called by muse, mutect2, varscan2
- PIGO | c.1153A>C p.T385P | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV53055438; called by muse, mutect2, varscan2
- PIGV | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV50304802; called by muse, mutect2, varscan2
- PPP5C | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776101874, COSV50144404; called by muse, mutect2, varscan2
- RBM15 | c.2564A>G p.N855S | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as COSV63924454; called by muse, mutect2, varscan2
- RBP3 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782398712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL26 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV53447650; called by muse, mutect2, varscan2
- SCN2B | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 115/237 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs17121818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGMS2 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV62989791; called by muse, mutect2, varscan2
- TDRD6 | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV60178628; called by muse, mutect2, varscan2
- TRPM6 | c.3095-2A>T p.X1032_splice | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as COSV62522338; called by muse, mutect2, varscan2
- VRK1 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV53711546; called by muse, mutect2, varscan2
- ZBTB7A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59329119; called by muse, mutect2, varscan2
- ZDBF2 | c.6584A>G p.Y2195C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV65630005; called by muse, mutect2, varscan2
- KIF19 | c.1888del p.E630Kfs*45 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- STAG2 | c.992dup p.Y331* | Nonsense Mutation (INS) | VAF 72/111 reads (65%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.453G>T p.V151= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV66065961; called by muse, mutect2, varscan2
- CAPZA3 | c.312C>A p.I104= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56858786; called by muse, mutect2, varscan2
- CASS4 | c.402C>T p.P134= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as rs201516954, COSV64387884; called by muse, mutect2, varscan2
- CLRN1 | c.294C>T p.H98= (on ENST00000327047 / NM_174878.3; = p.H22= on NM_052995.2) | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs774407660, COSV55806414; called by muse, mutect2, varscan2
- CRK | c.147C>T p.L49= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV56029671; called by muse, mutect2, varscan2
- H4C7 | c.93C>T p.T31= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV55100966; called by muse, mutect2, varscan2
- IGKV1D-17 | c.168C>T p.A56= | Silent (SNP) | VAF 138/396 reads (35%) | catalogued as rs547527855; called by muse, mutect2, varscan2
- PIAS4 | c.231G>A p.P77= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs757949859, COSV53678313; called by muse, mutect2, varscan2
- RPH3A | c.267C>T p.N89= (on ENST00000389385 / NM_001143854.2; = p.N85= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/164 reads (46%) | catalogued as rs112146970, COSV66991700, COSV66992995; called by muse, mutect2, varscan2
- SYNE1 | c.1590C>T p.Y530= (on ENST00000367255 / NM_182961.4; = p.Y537= on NM_033071.3) | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as rs369178017; called by muse, mutect2, varscan2
- TRDMT1 | c.1104G>A p.Q368= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV60841563; called by muse, mutect2, varscan2
- TUBB2B | c.633C>T p.C211= | Silent (SNP) | VAF 18/251 reads (7%) | catalogued as COSV52534475; called by muse, mutect2
- TUBGCP5 | c.630A>G p.P210= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1264644871; called by muse, mutect2, varscan2
- ZBTB12 | c.24G>A p.L8= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV64994205; called by muse, mutect2, varscan2
